Somatic mutation profile of tumor specimen TCGA-R8-A6MO-01A (aliquot TCGA-R8-A6MO-01A-11D-A33T-08) from TCGA case TCGA-R8-A6MO, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 53.2 years (19,432 days).
Specimen TCGA-R8-A6MO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbde50bc-cc9a-47cf-aa42-3298592df397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R8-A6MO-10C (Blood Derived Normal), aliquot TCGA-R8-A6MO-10C-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c0f0feb-e712-4fec-92ca-193ac873052f

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 2, Intron 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 51/87 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 63/209 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 59/181 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV99426952; called by muse, mutect2, varscan2
- ASAH1 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV100025732; called by muse, mutect2, varscan2
- CHRDL1 | c.967G>T p.E323* (on ENST00000372045; = p.E329* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 129/369 reads (35%) | catalogued as COSV99488203; called by muse, mutect2, varscan2
- CPEB4 | c.1962+2T>C p.X654_splice | Splice Site (SNP) | VAF 65/188 reads (35%) | catalogued as COSV54177007; called by muse, mutect2, varscan2
- EGFLAM | c.3041G>T p.C1014F (on ENST00000354891 / NM_001205301.2; = p.C1006F on NM_152403.4) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100380318; called by muse, mutect2, varscan2
- EPHA3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs867835679, COSV60701493; called by muse, mutect2, varscan2
- FRAS1 | c.3257G>C p.G1086A | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99352438; called by muse, mutect2, varscan2
- IGSF10 | c.2885G>A p.S962N | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs748648765, COSV99180366; called by muse, mutect2, varscan2
- ITGB6 | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324579; called by muse, mutect2, varscan2
- LRGUK | c.1811A>G p.E604G | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV53643394, COSV99604261; called by muse, mutect2, varscan2
- LRP2 | c.4630A>G p.T1544A | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.678); catalogued as COSV55579652; called by muse, mutect2, varscan2
- MUC4 | c.2386C>T p.R796* | Nonsense Mutation (SNP) | VAF 70/238 reads (29%) | catalogued as rs1277039508, COSV100640597; called by muse, mutect2, varscan2
- PA2G4 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs762145974, COSV100306500; called by muse, mutect2, varscan2
- PPBP | c.120A>C p.Q40H | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99933024; called by muse, mutect2, varscan2
- RBBP6 | c.4579G>A p.G1527R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100154620; called by muse, mutect2, varscan2
- RYR2 | c.6269G>A p.R2090Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1379845021, COSV63675160; called by muse, mutect2, varscan2
- SAMSN1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV99581524; called by muse, mutect2
- SETDB1 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250094191, COSV54990363; called by muse, mutect2, varscan2
- SRSF3 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as COSV100244853; called by muse, mutect2, varscan2
- TIMD4 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV99192643, COSV99192840; called by muse, mutect2, varscan2
- CCDC60 | c.300C>T p.A100= | Silent (SNP) | VAF 105/374 reads (28%) | catalogued as rs753492770, COSV100555155; called by muse, mutect2, varscan2
- CPEB2 | c.2427T>C p.F809= | Silent (SNP) | VAF 119/347 reads (34%) | catalogued as rs751897927, COSV99470351; called by muse, mutect2, varscan2
- FHDC1 | c.483A>G p.R161= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs1386539151, COSV99471315; called by muse, mutect2, varscan2
- IGHA2 | c.663G>A p.P221= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs781940614; called by muse, mutect2, varscan2
- IRX5 | c.675G>A p.A225= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100315838; called by muse, mutect2, varscan2
- MAGEA6 | c.777G>T p.R259= | Silent (SNP) | VAF 189/545 reads (35%) | catalogued as COSV100262834, COSV61449250; called by muse, mutect2, varscan2
- SORCS2 | c.1104C>A p.V368= | Silent (SNP) | VAF 52/398 reads (13%) | catalogued as rs748806977, COSV61172971; called by muse, mutect2, varscan2
- TRMT6 | c.141C>T p.F47= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs374176622; called by muse, mutect2, varscan2
- PNCK | c.-2-170G>T | Intron (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100562324; called by muse, mutect2, varscan2
- SORBS2 | c.685-7517del | Intron (DEL) | VAF 80/284 reads (28%) | called by mutect2, pindel, varscan2
- XIST | n.8700C>T | RNA (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
